Somatic mutation profile of tumor specimen C3L-02347-02 (aliquot CPT0113850009) from CPTAC case C3L-02347, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.6 years (22,868 days).
Specimen C3L-02347-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f49ae5-4f86-48ac-9451-f0878b4e3f27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02347-31 (Blood Derived Normal), aliquot CPT0115290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/244ffa6e-a224-4286-af88-57bcce524d6a

The open-access MAF lists 422 somatic variants for this specimen: 299 protein-altering or splice-affecting, 74 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 74, Frame Shift Del 69, Intron 30, Frame Shift Ins 13, 3'UTR 7, Nonsense Mutation 6, Splice Site 5, 5'UTR 5, RNA 3, Splice Region 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 44/193 reads (23%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 31/216 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 71/207 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen possibly damaging (0.599); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1922A>G p.K641R | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519047, CM020142, COSV60644280; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 14/386 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.1105del p.L369Wfs*7 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as COSV100086020; called by mutect2, pindel, varscan2
- ACP4 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs1457872555; called by muse, mutect2
- ACTR1A | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746393164, COSV53266578, COSV53266714; called by muse, mutect2, varscan2
- ACVR1 | c.111_112dup p.E38Vfs*21 | Frame Shift Ins (INS) | VAF 34/160 reads (21%) | catalogued as rs141073095; called by mutect2, varscan2
- AHDC1 | c.3538G>A p.G1180R | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs754321656, COSV55937744; called by muse, mutect2, varscan2
- ART5 | c.679dup p.H227Pfs*2 | Frame Shift Ins (INS) | VAF 67/193 reads (35%) | catalogued as rs748137393; called by mutect2, varscan2
- ATP4A | c.2095A>G p.M699V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs1468255225; called by muse, mutect2, varscan2
- BARX1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1235663514; called by muse, mutect2
- BCL3 | c.220dup p.H74Pfs*51 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | catalogued as rs770262318; called by mutect2, varscan2
- BICC1 | c.471del p.V158* | Frame Shift Del (DEL) | VAF 13/136 reads (10%) | catalogued as rs1198651930, COSV65857425; called by mutect2, pindel
- BRINP1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs571679824, COSV56296546, COSV56305962; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs751388819; called by mutect2, varscan2
- C12orf66 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs566655147; called by muse, mutect2, varscan2
- C15orf61 | c.280A>G p.K94E | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1481451901; called by muse, mutect2
- C1QTNF4 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.041); catalogued as rs1270421719; called by muse, mutect2, varscan2
- C1orf210 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs758379227; called by muse, mutect2, varscan2
- CACNA1A | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 142/410 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV64194831; called by muse, mutect2, varscan2
- CACNA1G | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs562004080, COSV61732564; called by muse, mutect2
- CACNA1H | c.4717C>T p.R1573* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | catalogued as rs1567543511, COSV61989232; called by muse, mutect2
- CACNG3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248441351, COSV50064358; called by muse, mutect2, varscan2
- CASKIN1 | c.2274dup p.V759Rfs*14 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | catalogued as rs1366170534; called by mutect2, pindel, varscan2
- CCDC105 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52964641; called by muse, mutect2, varscan2
- CHD5 | c.5717G>A p.R1906H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1296476872; called by muse, mutect2, varscan2
- CHERP | c.1362del p.W455Gfs*200 | Frame Shift Del (DEL) | VAF 41/252 reads (16%) | catalogued as rs770045437; called by mutect2, pindel, varscan2
- CHRNA10 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 31/357 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1385246856; called by muse, mutect2
- CHRNA7 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 141/819 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs568931594, COSV60974599; called by muse, mutect2, varscan2
- CILP2 | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs758866374; called by muse, mutect2, varscan2
- CLIC6 | c.1561C>A p.L521M (on ENST00000360731 / NM_001317009.2; = p.L503M on NM_053277.3) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401328825; called by muse, mutect2
- CNTROB | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 153/443 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66609545; called by muse, mutect2, varscan2
- COL4A5 | c.4378C>T p.H1460Y | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60370361; called by muse, mutect2
- COL6A6 | c.5725G>A p.A1909T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs953900662, COSV100650603; called by muse, mutect2
- CPNE8 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.207); catalogued as rs1025322893; called by muse, mutect2, varscan2
- CTU1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 214/637 reads (34%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.907); catalogued as rs996215928; called by muse, mutect2
- CYP2D6 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 39/656 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs763462589; called by muse, mutect2
- DAPK3 | c.995C>A p.A332E | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs372041714; called by muse, mutect2
- DCAF8L1 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs754851379, COSV101491472, COSV71595232; called by muse, mutect2
- DCHS1 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs187784912, COSV55034085; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs773554787; called by mutect2, pindel, varscan2
- DENND2A | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs558395690, COSV104369962; called by muse, mutect2
- DIDO1 | c.6200C>T p.S2067L | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99825685; called by muse, mutect2, varscan2
- DLC1 | c.3242C>T p.T1081M (on ENST00000276297 / NM_001348081.2; = p.T644M on NM_006094.5) | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs752787691; called by muse, mutect2, varscan2
- DNAH9 | c.10596del p.G3533Dfs*40 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | catalogued as COSV52345258; called by mutect2, pindel
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 25/120 reads (21%) | catalogued as rs748560644; called by mutect2, varscan2
- EPHB2 | c.1927C>T p.P643S (on ENST00000400191 / NM_001309193.2; = p.P644S on NM_004442.7) | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV104424382, COSV65867188; called by muse, mutect2
- EZH2 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57448017, COSV57458207; called by muse, mutect2, varscan2
- FAM184B | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1400852491; called by muse, mutect2, varscan2
- FAT1 | c.9683del p.P3228Lfs*42 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | catalogued as rs1010116749; called by mutect2, pindel
- FBLL1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV57924708; called by muse, mutect2, varscan2
- FBXL8 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 328/877 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs747897712; called by muse, mutect2, varscan2
- FEZ1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs762054096; called by muse, mutect2, varscan2
- FLYWCH1 | c.1688G>A p.R563H (on ENST00000253928 / NM_001308068.2; = p.R562H on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/376 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs780119016, COSV54146729, COSV99558613; called by muse, mutect2, varscan2
- FOXJ1 | c.161dup p.T57Hfs*142 | Frame Shift Ins (INS) | VAF 23/88 reads (26%) | catalogued as COSV53948415; called by mutect2, pindel, varscan2
- FXR2 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 53/176 reads (30%) | catalogued as rs772910721; called by muse, mutect2, varscan2
- GAL3ST1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as rs753448980, COSV58893105; called by mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 84/226 reads (37%) | catalogued as rs771881138; called by mutect2, varscan2
- GPC2 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs763174733; called by muse, mutect2, varscan2
- GRIPAP1 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.475); catalogued as COSV64551464; called by muse, mutect2, varscan2
- GTF3C3 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs997441975, COSV55834516; called by muse, mutect2
- HASPIN | c.1782del p.F594Lfs*19 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1199479648; called by mutect2, pindel, varscan2
- HCN1 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs772962018, COSV57526034; called by muse, mutect2, varscan2
- HEATR1 | c.4157C>T p.A1386V | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781325001, COSV63983179; called by muse, mutect2, varscan2
- INPPL1 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1394942069, COSV53353340; called by muse, mutect2, varscan2
- JPH2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 79/831 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV100881549; called by muse, mutect2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as COSV54711577; called by mutect2, varscan2
- KLHL17 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 99/370 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.419); catalogued as rs1233603974, COSV58533668; called by muse, mutect2, varscan2
- KRT34 | c.876+1G>A p.X292_splice | Splice Site (SNP) | VAF 6/108 reads (6%) | catalogued as rs376395697; called by muse, mutect2
- L1CAM | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as rs369812595; called by muse, mutect2, varscan2
- LAMA3 | c.4973del p.P1658Lfs*91 | Frame Shift Del (DEL) | VAF 95/437 reads (22%) | catalogued as rs759440110; called by mutect2, pindel, varscan2
- LRP2 | c.11452G>A p.D3818N | Missense Mutation (SNP) | VAF 110/406 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.208); catalogued as COSV55552810; called by muse, mutect2, varscan2
- LRRC20 | c.547dup p.L183Pfs*59 (on ENST00000355790 / NM_207119.3; = p.L127Pfs*59 on NM_018205.4) | Frame Shift Ins (INS) | VAF 29/110 reads (26%) | catalogued as rs768741708; called by mutect2, pindel, varscan2
- MAP6D1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 170/432 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs868388777; called by muse, mutect2, varscan2
- MARCHF6 | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs1308180572; called by muse, mutect2
- MC5R | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 130/357 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs1176809042; called by muse, mutect2, varscan2
- MMEL1 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 47/225 reads (21%) | catalogued as rs771512368; called by muse, mutect2, varscan2
- MPZL1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs190661858; called by muse, mutect2, varscan2
- MRE11 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100119358; called by muse, mutect2, varscan2
- MTMR3 | c.1813del p.L605* | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as COSV60305229; called by mutect2, pindel, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 63/234 reads (27%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYO1D | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 182/555 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757145678, COSV59012237; called by muse, mutect2, varscan2
- NEB | c.16502G>A p.R5501H | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs769388036, COSV51177927; called by muse, mutect2, varscan2
- NFKBIZ | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as rs773954147; called by muse, mutect2
- NOL12 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs777378040, COSV63031068; called by muse, mutect2, varscan2
- NUP210 | c.531G>A p.L177= | Splice Region (SNP) | VAF 33/177 reads (19%) | catalogued as COSV54402253; called by muse, mutect2, varscan2
- OGG1 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs1226759838; called by muse, mutect2, varscan2
- P3H1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 110/345 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs369342678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAQR8 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as rs1367645207, COSV62441986, COSV62443700; called by muse, mutect2
- PCDHGA2 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 184/544 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as COSV54040233; called by muse, mutect2, varscan2
- PCDHGB4 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 52/448 reads (12%) | catalogued as COSV53914987; called by muse, varscan2
- PCNT | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs777707751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 66/186 reads (35%) | catalogued as rs769717544; called by mutect2, varscan2
- PHRF1 | c.1975C>T p.R659C (on ENST00000264555 / NM_001286581.2; = p.R658C on NM_020901.4) | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs192557368; called by muse, mutect2
- PLEC | c.12212G>A p.C4071Y (on ENST00000322810 / NM_201380.4; = p.C3961Y on NM_000445.5) | Missense Mutation (SNP) | VAF 19/582 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV59684134; called by muse, mutect2
- PLEC | c.1178C>T p.S393L (on ENST00000322810 / NM_201380.4; = p.S283L on NM_000445.5) | Missense Mutation (SNP) | VAF 147/479 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782798891, COSV59604630; called by muse, mutect2, varscan2
- PLK4 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1039225992; called by muse, mutect2
- PNPLA6 | c.958A>G p.M320V (on ENST00000414982 / NM_001166111.2; = p.M272V on NM_006702.5) | Missense Mutation (SNP) | VAF 86/365 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs947135990; called by muse, mutect2, varscan2
- POU5F1B | c.73del p.A25Rfs*9 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as COSV101197043; called by mutect2, pindel, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 110/281 reads (39%) | catalogued as rs763475304; called by mutect2, varscan2
- PPOX | c.342del p.X114_splice | Splice Site (DEL) | VAF 57/383 reads (15%) | catalogued as CS0911074; called by mutect2, pindel, varscan2
- PPP1R3F | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs148829919, COSV50019616, COSV50020480; called by mutect2, varscan2
- PRR15 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1272118888; called by muse, mutect2, varscan2
- PRR32 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV64420587; called by muse, mutect2, varscan2
- PRSS1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs144403091, CM011004, COSV61192213; ClinVar: uncertain significance; called by muse, mutect2
- PTEN | c.604del p.T202Lfs*19 | Frame Shift Del (DEL) | VAF 50/157 reads (32%) | catalogued as COSV104426444; called by mutect2, pindel, varscan2
- QSER1 | c.800C>T p.A267V (on ENST00000399302; = p.A396V on NM_001076786.3) | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1316781879, COSV67901800; called by muse, mutect2, varscan2
- RACK1 | c.348C>G p.D116E | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV65175499; called by muse, mutect2, varscan2
- RAD9A | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs549233956, COSV57237338, COSV57237625; called by muse, mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RFX8 | c.1325C>T p.A442V (on ENST00000646446; = p.A371V on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/454 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs375170866; called by muse, mutect2, varscan2
- RHCG | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs140495230; called by muse, mutect2
- RIC1 | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs143659237, COSV52612299; called by muse, mutect2, varscan2
- RIMBP3 | c.1718T>C p.L573P | Missense Mutation (SNP) | VAF 225/1577 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276986746; called by muse, mutect2, varscan2
- RLIM | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61754467, COSV60325260, COSV60326085; called by muse, mutect2, varscan2
- ROBO1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs765000690, COSV101458240, COSV71395171; called by muse, mutect2
- RYR2 | c.9693G>A p.M3231I | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs748858246; called by muse, mutect2, varscan2
- SALL4 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 58/700 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53857383; called by muse, mutect2
- SCART1 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1043834419; called by muse, mutect2, varscan2
- SEC23IP | c.2272G>C p.V758L | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1452824139; called by muse, mutect2, varscan2
- SETD2 | c.7447G>A p.V2483I | Missense Mutation (SNP) | VAF 22/351 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs141852778; ClinVar: uncertain significance; called by muse, mutect2
- SF3A1 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs1476992303; called by muse, mutect2, varscan2
- SH2D3A | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV55585850; called by muse, mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | catalogued as rs752843778; called by mutect2, varscan2
- SHOX2 | c.425G>A p.R142Q (on ENST00000441443 / NM_006884.3; = p.R166Q on NM_003030.4) | Missense Mutation (SNP) | VAF 183/579 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67463773; called by muse, mutect2, varscan2
- SLC12A4 | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746962872; called by muse, mutect2
- SLC12A7 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 123/332 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs1354395478; called by muse, mutect2, varscan2
- SLC22A3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778599126; called by muse, mutect2, varscan2
- SLC35G4 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 170/521 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs771787793; called by muse, mutect2, varscan2
- SLC5A8 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746207517; called by muse, mutect2, varscan2
- SPATA5L1 | c.2062dup p.S688Ffs*4 | Frame Shift Ins (INS) | VAF 37/128 reads (29%) | catalogued as rs747183050; called by mutect2, varscan2
- SPIN2B | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 136/436 reads (31%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.973); catalogued as rs924017959; called by muse, mutect2, varscan2
- SPIRE2 | c.1391del p.P464Qfs*53 | Frame Shift Del (DEL) | VAF 62/184 reads (34%) | catalogued as rs1187128946; called by mutect2, varscan2
- STEAP3 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 198/665 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs760800930; called by muse, mutect2, varscan2
- SV2C | c.1421A>G p.E474G | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1157522418; called by muse, mutect2, varscan2
- SYNE2 | c.4024G>A p.V1342I | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs747274988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.13525C>T p.R4509C | Missense Mutation (SNP) | VAF 100/424 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs752451899; called by muse, mutect2, varscan2
- SYNPO | c.1853G>A p.R618Q (on ENST00000394243 / NM_001166208.2; = p.R374Q on NM_007286.6) | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201771817, COSV56938060; called by muse, mutect2, varscan2
- SYT6 | c.389C>T p.A130V (on ENST00000610222 / NM_001366225.1; = p.A45V on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs762223986, COSV65772933; called by muse, mutect2, varscan2
- TBRG4 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs777121100, COSV51833151; called by muse, mutect2
- TBX1 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 38/529 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60355170; called by muse, mutect2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs758822980; called by mutect2, varscan2
- TENT5B | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.53); catalogued as rs761964269, COSV56693337; called by muse, mutect2, varscan2
- TIA1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568284639; called by muse, mutect2, varscan2
- TMED2 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1423247488; called by muse, mutect2, varscan2
- TNC | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs45481099; called by muse, mutect2, varscan2
- TNK1 | c.234G>A p.K78= | Splice Region (SNP) | VAF 62/198 reads (31%) | catalogued as COSV100295058; called by muse, mutect2, varscan2
- TOM1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs11558473; called by muse, mutect2, varscan2
- TRIM72 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs763394921; called by muse, mutect2, varscan2
- TRMT61A | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs756077573, COSV54569294; called by muse, mutect2, varscan2
- TRPM6 | c.5747G>A p.R1916Q | Missense Mutation (SNP) | VAF 169/472 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs759362850, COSV62517785; called by muse, mutect2, varscan2
- TSPAN10 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 29/362 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs771337272, COSV100148454; called by muse, mutect2
- TSSK1B | c.1075del p.Q359Nfs*43 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | catalogued as rs747842861, COSV101181233; called by mutect2, pindel, varscan2
- TULP4 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324493664, COSV100893494; called by muse, mutect2, varscan2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 45/168 reads (27%) | catalogued as rs780272979; called by mutect2, pindel, varscan2
- VAV2 | c.685C>T p.R229W (on ENST00000371850 / NM_001134398.2; = p.R224W on NM_003371.4) | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs546008982; called by muse, mutect2, varscan2
- VNN1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs372898370; called by muse, mutect2, varscan2
- VWA5B2 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs939096985; called by muse, mutect2, varscan2
- YTHDF1 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.114); catalogued as COSV64833501; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2573C>T p.T858M | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1262650181, COSV54296407; called by muse, mutect2, varscan2
- ZFHX3 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.137); catalogued as rs758323451, COSV51710677; called by muse, mutect2, varscan2
- ZNF521 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 77/242 reads (32%) | catalogued as COSV64130387; called by muse, mutect2, varscan2
- ZNF716 | c.381del p.K127Nfs*6 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs781946785; called by mutect2, varscan2
- AADACL3 | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ADAMTS7 | c.2519-2A>G p.X840_splice | Splice Site (SNP) | VAF 55/223 reads (25%) | called by muse, mutect2, varscan2
- ADNP | c.559del p.E187Nfs*11 | Frame Shift Del (DEL) | VAF 30/109 reads (28%) | called by mutect2, pindel, varscan2
- AGO2 | c.2557_2558del p.L853Afs*13 | Frame Shift Del (DEL) | VAF 56/206 reads (27%) | called by pindel, varscan2
- AMIGO2 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AQP8 | c.364A>G p.M122V | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | called by mutect2, varscan2
- ARHGAP20 | c.3204dup p.G1069Rfs*31 | Frame Shift Ins (INS) | VAF 32/113 reads (28%) | called by mutect2, pindel, varscan2
- ARID1A | c.5553dup p.T1852Hfs*2 | Frame Shift Ins (INS) | VAF 67/249 reads (27%) | called by mutect2, pindel, varscan2
- ARID1B | c.1384del p.A462Rfs*40 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by pindel, varscan2
- ASH1L | c.4264C>G p.P1422A | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASXL3 | c.2625del p.V876Cfs*59 | Frame Shift Del (DEL) | VAF 35/168 reads (21%) | called by mutect2, varscan2
- ATM | c.1757A>G p.E586G | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by mutect2, varscan2
- ATP13A2 | c.905del p.G302Efs*11 | Frame Shift Del (DEL) | VAF 26/293 reads (9%) | called by pindel, varscan2
- BAG3 | c.715del p.E239Sfs*68 | Frame Shift Del (DEL) | VAF 76/284 reads (27%) | called by mutect2, pindel, varscan2
- BAZ1B | c.1360C>A p.P454T | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- BEND4 | c.264del p.G91Afs*23 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- BHMT2 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRWD3 | c.3632G>A p.R1211H | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPN2 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- CARD6 | c.1267del p.A423Pfs*2 | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | called by mutect2, pindel, varscan2
- CCNT2 | c.303_305delinsT p.E101Dfs*20 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | called by pindel, varscan2*
- CDK12 | c.4277G>T p.S1426I (on ENST00000447079 / NM_016507.4; = p.S1417I on NM_015083.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); called by muse, mutect2
- CDS1 | c.1343A>G p.H448R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CPEB2 | c.1024C>A p.L342M | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2
- CRHBP | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CT47B1 | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 153/526 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CTCF | c.1669_1672del p.C557Lfs*26 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | called by mutect2, pindel, varscan2
- CTIF | c.1752del p.I585Sfs*12 | Frame Shift Del (DEL) | VAF 127/513 reads (25%) | called by mutect2, pindel, varscan2
- CUX2 | c.2981C>A p.P994H | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDN | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DDX1 | c.2099G>C p.S700T | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- DNAJC1 | c.1569_1570del p.A524Qfs*14 | Frame Shift Del (DEL) | VAF 55/142 reads (39%) | called by mutect2, pindel, varscan2
- DNASE1L2 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DZIP3 | c.1352T>C p.L451P | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EBF3 | c.833del p.G278Vfs*6 (on ENST00000355311 / NM_001375392.1; = p.G269Vfs*6 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/344 reads (9%) | called by mutect2, pindel
- ELP1 | c.2737-3del | Splice Region (DEL) | VAF 21/69 reads (30%) | called by mutect2, pindel
- EPS8L2 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- EPX | c.1709-1G>T p.X570_splice | Splice Site (SNP) | VAF 46/485 reads (9%) | called by muse, mutect2
- ERC2 | c.63G>T p.L21F | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ERRFI1 | c.353_356del p.L118Qfs*2 | Frame Shift Del (DEL) | VAF 79/122 reads (65%) | called by mutect2, pindel, varscan2
- EXOC1 | c.2259del p.E754Kfs*18 | Frame Shift Del (DEL) | VAF 37/112 reads (33%) | called by mutect2, varscan2
- FAM193A | c.2497dup p.M833Nfs*12 | Frame Shift Ins (INS) | VAF 76/241 reads (32%) | called by mutect2, varscan2
- FBXL8 | c.735G>T p.L245F | Missense Mutation (SNP) | VAF 334/886 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- FLT1 | c.2700G>T p.K900N | Missense Mutation (SNP) | VAF 21/670 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- FUCA2 | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FYCO1 | c.3817A>G p.R1273G | Missense Mutation (SNP) | VAF 117/509 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GANAB | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GINS3 | c.293C>G p.T98S | Missense Mutation (SNP) | VAF 170/517 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- GRIA4 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.829); called by muse, mutect2
- GRIK2 | c.482del p.L161* | Frame Shift Del (DEL) | VAF 72/286 reads (25%) | called by mutect2, pindel, varscan2
- HHEX | c.97del p.Y33Tfs*75 | Frame Shift Del (DEL) | VAF 68/396 reads (17%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- HNRNPH2 | c.885del p.L296Yfs*20 | Frame Shift Del (DEL) | VAF 33/129 reads (26%) | called by mutect2, pindel, varscan2
- HSP90AB1 | c.1041G>C p.K347N | Missense Mutation (SNP) | VAF 74/338 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HSPA9 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 176/461 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INPPL1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ITGAM | c.154del p.Q52Rfs*3 | Frame Shift Del (DEL) | VAF 62/175 reads (35%) | called by mutect2, pindel, varscan2
- ITPR2 | c.5509del p.R1837Gfs*7 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 108/250 reads (43%) | called by mutect2, varscan2
- JARID2 | c.1186del p.A396Rfs*18 | Frame Shift Del (DEL) | VAF 32/161 reads (20%) | called by mutect2, pindel, varscan2
- KAT7 | c.1190A>T p.E397V | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KIAA1614 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KIF1A | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- KIFC3 | c.2075G>T p.R692L | Missense Mutation (SNP) | VAF 22/580 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2
- KLHL41 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- KNL1 | c.4526C>T p.A1509V (on ENST00000346991 / NM_170589.5; = p.A1483V on NM_144508.5) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP11-1 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 29/332 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2
- LAMB4 | c.2320del p.Q774Rfs*59 | Frame Shift Del (DEL) | VAF 85/243 reads (35%) | called by mutect2, pindel, varscan2
- LAMC3 | c.2336del p.P779Rfs*105 | Frame Shift Del (DEL) | VAF 48/192 reads (25%) | called by mutect2, pindel, varscan2
- LHX4 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 108/531 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- LINGO1 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1 | c.12101C>T p.T4034M | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRN4 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2
- LRTM2 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MAP7D1 | c.107del p.P36Hfs*20 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- MAST4 | c.6805G>A p.G2269S (on ENST00000403625 / NM_001164664.2; = p.G2080S on NM_015183.3) | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLLT6 | c.1182del p.F394Lfs*55 | Frame Shift Del (DEL) | VAF 109/427 reads (26%) | called by mutect2, pindel, varscan2
- MN1 | c.1347del p.Y450Tfs*2 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | called by mutect2, pindel, varscan2
- NCBP3 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 116/312 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NDST1 | c.1905del p.S636Afs*65 | Frame Shift Del (DEL) | VAF 54/522 reads (10%) | called by mutect2, pindel, varscan2
- NFE2L3 | c.1744A>G p.I582V | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NHS | c.4476del p.N1493Mfs*27 | Frame Shift Del (DEL) | VAF 148/470 reads (31%) | called by mutect2, pindel, varscan2
- NOC4L | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 170/472 reads (36%) | called by mutect2, varscan2
- NSD1 | c.5508del p.A1837Lfs*12 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- NTN3 | c.344T>C p.F115S | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBSCN | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 124/545 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OBSCN | c.7217C>T p.S2406L | Missense Mutation (SNP) | VAF 86/461 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR10K1 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); called by muse, mutect2
- OR8D1 | c.562T>G p.S188A | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PCDHA3 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.12); called by muse, mutect2
- PCED1B | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCNX1 | c.2311+2T>C p.X771_splice | Splice Site (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- PCOLCE | c.916del p.T306Qfs*34 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- PIK3CB | c.1813del p.E605Rfs*3 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | called by mutect2, pindel, varscan2
- PLEC | c.11848dup p.R3950Pfs*55 (on ENST00000322810 / NM_201380.4; = p.R3840Pfs*55 on NM_000445.5) | Frame Shift Ins (INS) | VAF 40/209 reads (19%) | called by mutect2, pindel, varscan2
- PTEN | c.113_118del p.P38_E40delinsQ | In Frame Del (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel, varscan2
- PTOV1 | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 27/456 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- PTPA | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- QPRT | c.383C>G p.A128G | Missense Mutation (SNP) | VAF 129/378 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAD54L2 | c.266A>G p.Q89R | Missense Mutation (SNP) | VAF 129/634 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAD9A | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBBP6 | c.4594del p.S1532Vfs*30 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- RBBP8 | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- REV3L | c.4070del p.N1357Ifs*12 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- RGS4 | c.590G>A p.C197Y | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen possibly damaging (0.735); called by muse, mutect2
- RTN2 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 167/431 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHANK3 | c.4766del p.G1589Afs*35 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- SIX5 | c.49del p.E17Rfs*91 | Frame Shift Del (DEL) | VAF 96/168 reads (57%) | called by mutect2, varscan2
- SLC15A5 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.847); called by muse, mutect2
- SLC25A1 | c.543C>G p.Y181* | Nonsense Mutation (SNP) | VAF 14/372 reads (4%) | called by muse, mutect2
- SLC25A18 | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A11 | c.717C>G p.N239K | Missense Mutation (SNP) | VAF 129/440 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPO11 | c.1000del p.R334Gfs*4 | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- STKLD1 | c.1092G>C p.W364C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2
- SULF1 | c.1354_1357del p.T452Pfs*73 | Frame Shift Del (DEL) | VAF 39/193 reads (20%) | called by mutect2, pindel, varscan2
- SUPT20H | c.808dup p.R270Kfs*11 (on ENST00000350612 / NM_001014286.3; = p.R271Kfs*11 on NM_017569.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- SUV39H1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 109/336 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TAF7L | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- TBC1D8 | c.3053C>T p.A1018V | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- TIAL1 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- TLCD5 | c.526G>A p.G176R (on ENST00000375095 / NM_001198671.2; = p.G198R on NM_001198670.2) | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBB | c.1015_1017del p.S339del | In Frame Del (DEL) | VAF 26/188 reads (14%) | called by pindel, varscan2
- UBE2I | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.114); called by muse, mutect2
- UTP20 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- WFDC5 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB33 | c.592del p.C198Afs*43 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- ZC3H7A | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ZNF292 | c.3053dup p.Q1019Tfs*31 | Frame Shift Ins (INS) | VAF 44/174 reads (25%) | called by mutect2, pindel, varscan2
- ZNF676 | c.1726A>G p.R576G (on ENST00000650058; = p.R544G on NM_001001411.3) | Missense Mutation (SNP) | VAF 11/316 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.111); called by muse, mutect2
- ACTRT1 | c.528C>T p.H176= | Silent (SNP) | VAF 62/212 reads (29%) | catalogued as rs140288728, COSV100947550, COSV100947755; called by muse, mutect2, varscan2
- AHDC1 | c.1197C>T p.A399= | Silent (SNP) | VAF 52/225 reads (23%) | catalogued as rs1469795705; called by muse, mutect2, varscan2
- ANK1 | c.3774C>T p.C1258= | Silent (SNP) | VAF 17/414 reads (4%) | called by muse, mutect2
- ANKRD35 | c.2926C>T p.L976= | Silent (SNP) | VAF 46/212 reads (22%) | called by muse, mutect2, varscan2
- ARMC5 | c.979C>T p.L327= | Silent (SNP) | VAF 14/359 reads (4%) | called by muse, mutect2
- ATP1B4 | c.897C>T p.Y299= (on ENST00000218008 / NM_001142447.3; = p.Y295= on NM_012069.5) | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as rs148650396, COSV54311543; called by muse, mutect2, varscan2
- AURKB | c.624A>G p.L208= | Silent (SNP) | VAF 14/315 reads (4%) | called by muse, mutect2
- BCL9L | c.3846C>T p.G1282= | Silent (SNP) | VAF 83/236 reads (35%) | called by muse, mutect2, varscan2
- C3 | c.4575C>T p.D1525= | Silent (SNP) | VAF 16/533 reads (3%) | called by muse, mutect2
- CCR9 | c.774T>C p.T258= (on ENST00000357632 / NM_031200.3; = p.T246= on NM_006641.4) | Silent (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- CEACAM16 | c.822C>T p.G274= | Silent (SNP) | VAF 77/349 reads (22%) | called by muse, mutect2, varscan2
- CELF4 | c.63C>T p.N21= | Silent (SNP) | VAF 69/168 reads (41%) | catalogued as COSV58450185; called by muse, mutect2, varscan2
- CIT | c.5832C>T p.P1944= | Silent (SNP) | VAF 30/562 reads (5%) | catalogued as rs1245287791; called by muse, mutect2
- CNGA2 | c.1776C>T p.S592= | Silent (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- CRIP1 | c.114G>A p.L38= | Silent (SNP) | VAF 84/228 reads (37%) | called by muse, mutect2, varscan2
- DGKZ | c.1143G>A p.Q381= (on ENST00000454345 / NM_001105540.2; = p.Q193= on NM_003646.4) | Silent (SNP) | VAF 24/136 reads (18%) | called by muse, varscan2
- DNPEP | c.1182C>T p.N394= | Silent (SNP) | VAF 57/311 reads (18%) | catalogued as rs751244985, COSV56111551; called by muse, mutect2, varscan2
- ELFN1 | c.1224G>A p.P408= | Silent (SNP) | VAF 22/261 reads (8%) | catalogued as rs368802923; called by muse, mutect2
- FBRS | c.906G>T p.R302= (on ENST00000287468; = p.R822= on NM_001105079.3) | Silent (SNP) | VAF 38/678 reads (6%) | called by muse, mutect2
- FNDC3B | c.2121C>T p.S707= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs779882827, COSV61041475; called by muse, mutect2
- GOLGA6A | c.1608C>T p.D536= | Silent (SNP) | VAF 8/80 reads (10%) | called by mutect2, varscan2
- GPR25 | c.372C>T p.C124= | Silent (SNP) | VAF 242/631 reads (38%) | catalogued as rs1309893884; called by muse, mutect2, varscan2
- GRM7 | c.1053G>A p.T351= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs150722276; called by muse, mutect2, varscan2
- HECA | c.678G>A p.R226= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV62769771; called by muse, mutect2
- HES1 | c.627T>C p.A209= | Silent (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- IRX4 | c.873C>T p.A291= | Silent (SNP) | VAF 24/454 reads (5%) | catalogued as rs1182368536; called by muse, mutect2
- KCTD9 | c.582G>A p.P194= | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as rs748448553, COSV55339878; called by muse, mutect2, varscan2
- KDM6B | c.102T>C p.H34= | Silent (SNP) | VAF 121/563 reads (21%) | called by muse, mutect2, varscan2
- L1CAM | c.771G>A p.G257= | Silent (SNP) | VAF 63/602 reads (10%) | called by muse, mutect2, varscan2
- LGALS9 | c.678T>C p.P226= (on ENST00000395473 / NM_009587.3; = p.P194= on NM_002308.4) | Silent (SNP) | VAF 26/322 reads (8%) | catalogued as rs746075474; called by muse, mutect2
- MAGEL2 | c.1326G>A p.P442= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs550125705, COSV58569154; called by muse, mutect2, varscan2
- MAGEL2 | c.1176G>A p.T392= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV58568141; called by muse, mutect2, varscan2
- MINAR1 | c.1995C>T p.H665= | Silent (SNP) | VAF 30/344 reads (9%) | catalogued as rs757401665, COSV59586147; called by muse, mutect2
- MROH2A | c.4251C>T p.G1417= | Silent (SNP) | VAF 75/212 reads (35%) | catalogued as rs1206782968, COSV67682568; called by muse, mutect2, varscan2
- MROH5 | c.433C>T p.L145= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV71301722; called by muse, mutect2, varscan2
- MRPL34 | c.162G>A p.Q54= | Silent (SNP) | VAF 158/444 reads (36%) | called by muse, mutect2, varscan2
- MUC5B | c.11190C>T p.T3730= | Silent (SNP) | VAF 74/196 reads (38%) | catalogued as rs570124204, COSV101500855; called by mutect2, varscan2
- NLGN2 | c.333C>T p.H111= | Silent (SNP) | VAF 61/716 reads (9%) | catalogued as rs1203675474; called by muse, mutect2
- NOMO2 | c.1794C>T p.H598= | Silent (SNP) | VAF 59/422 reads (14%) | catalogued as rs369430880; called by muse, mutect2
- NOTCH3 | c.6174G>A p.S2058= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as rs1304790357, COSV54643297; ClinVar: uncertain significance; called by muse, mutect2
- NSUN7 | c.372C>T p.S124= | Silent (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- P3H3 | c.1395G>A p.E465= | Silent (SNP) | VAF 100/362 reads (28%) | called by muse, mutect2, varscan2
- PAX1 | c.87C>T p.G29= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV68272732; called by muse, mutect2
- PCDHGB4 | c.1938C>T p.D646= | Silent (SNP) | VAF 186/528 reads (35%) | catalogued as rs1253797821, COSV53914454; called by muse, varscan2
- PER3 | c.2481G>T p.L827= | Silent (SNP) | VAF 145/430 reads (34%) | called by muse, mutect2, varscan2
- PEX2 | c.732C>T p.C244= | Silent (SNP) | VAF 66/200 reads (33%) | catalogued as rs142121434; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHYKPL | c.909C>T p.G303= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as rs141654643; called by muse, mutect2, varscan2
- PRRX2 | c.639C>T p.P213= | Silent (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- PSMB11 | c.453C>T p.C151= | Silent (SNP) | VAF 76/232 reads (33%) | catalogued as rs755271648, COSV57458713, COSV57459122; called by muse, mutect2, varscan2
- RANGAP1 | c.396C>T p.F132= | Silent (SNP) | VAF 51/257 reads (20%) | catalogued as rs754622496, COSV62362651; called by muse, mutect2, varscan2
- RASA1 | c.1171C>A p.R391= | Silent (SNP) | VAF 9/182 reads (5%) | catalogued as COSV57198473; called by muse, mutect2
- RPS18 | c.111C>T p.G37= | Silent (SNP) | VAF 10/181 reads (6%) | called by muse, mutect2
- SALL1 | c.1905G>A p.P635= | Silent (SNP) | VAF 22/257 reads (9%) | catalogued as rs781104798, COSV51763379; called by muse, mutect2
- SAMSN1 | c.468C>T p.D156= | Silent (SNP) | VAF 104/386 reads (27%) | catalogued as rs372194779; called by muse, mutect2, varscan2
- SEMA3G | c.729G>A p.V243= | Silent (SNP) | VAF 58/230 reads (25%) | called by muse, varscan2
- SHANK2 | c.3054C>T p.N1018= | Silent (SNP) | VAF 180/768 reads (23%) | catalogued as rs782383457; called by muse, mutect2, varscan2
- SLC16A8 | c.654C>T p.G218= | Silent (SNP) | VAF 50/290 reads (17%) | called by muse, mutect2, varscan2
- SLC35A2 | c.279C>T p.N93= | Silent (SNP) | VAF 119/258 reads (46%) | catalogued as rs782206039, COSV54430736; called by muse, mutect2, varscan2
- SLC52A3 | c.126C>A p.S42= | Silent (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- SLCO3A1 | c.231C>T p.D77= | Silent (SNP) | VAF 46/526 reads (9%) | catalogued as COSV59240437; called by muse, mutect2
- SLFN11 | c.2463C>T p.H821= | Silent (SNP) | VAF 121/330 reads (37%) | called by muse, mutect2, varscan2
- SRCIN1 | c.1404G>A p.S468= (on ENST00000621492; = p.S434= on NM_025248.3) | Silent (SNP) | VAF 66/216 reads (31%) | called by muse, mutect2, varscan2
- SYT16 | c.909C>T p.G303= | Silent (SNP) | VAF 63/232 reads (27%) | called by muse, mutect2, varscan2
- TAS2R13 | c.208C>T p.L70= | Silent (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2, varscan2
- TBC1D9B | c.1548G>A p.E516= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- TECR | c.747C>A p.T249= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as rs778110804; called by muse, mutect2, varscan2
- TENM1 | c.4509G>A p.S1503= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as rs764225028, COSV100950422; called by muse, mutect2, varscan2
- TGFB1 | c.447G>A p.L149= | Silent (SNP) | VAF 180/418 reads (43%) | called by muse, mutect2, varscan2
- TJP3 | c.471C>T p.A157= | Silent (SNP) | VAF 119/447 reads (27%) | catalogued as rs554835600, COSV99516251; called by muse, mutect2, varscan2
- TMCO1 | c.612G>A p.S204= (on ENST00000612311 / NM_001256164.1; = p.S153= on NM_019026.6) | Silent (SNP) | VAF 56/208 reads (27%) | catalogued as rs370197616, COSV63318589; called by muse, mutect2, varscan2
- TMEM145 | c.1389G>A p.P463= | Silent (SNP) | VAF 75/251 reads (30%) | called by muse, mutect2, varscan2
- TRIM22 | c.987C>T p.C329= | Silent (SNP) | VAF 61/202 reads (30%) | called by muse, mutect2, varscan2
- ZNF132 | c.1215C>T p.C405= | Silent (SNP) | VAF 53/244 reads (22%) | called by muse, mutect2, varscan2
- ZZEF1 | c.8700T>C p.T2900= | Silent (SNP) | VAF 137/578 reads (24%) | called by muse, mutect2, varscan2
- AC074085.2 | n.101C>A | RNA (SNP) | VAF 117/346 reads (34%) | called by muse, mutect2, varscan2
- AC093525.2 | c.*496T>G | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- AGPAT3 | c.-48-4516C>T | Intron (SNP) | VAF 57/171 reads (33%) | catalogued as rs1490738542; called by muse, mutect2, varscan2
- AK2 | c.*377C>A | 3'UTR (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- AL121899.2 | c.*358A>G | 3'UTR (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- AL353804.7 | chrX:73850279 del A | 5'Flank (DEL) | VAF 16/72 reads (22%) | catalogued as rs762505968; called by mutect2, pindel, varscan2
- AP1G1 | c.-4+901del | Intron (DEL) | VAF 20/60 reads (33%) | catalogued as rs749517248; called by mutect2, varscan2
- ARFGAP1 | c.835-193C>T | Intron (SNP) | VAF 93/348 reads (27%) | catalogued as rs767080052, COSV100796748; called by muse, mutect2, varscan2
- ARHGDIA | c.*305G>A | 3'UTR (SNP) | VAF 29/128 reads (23%) | catalogued as rs369742215; called by muse, mutect2, varscan2
- ASB16 | c.570-18T>G | Intron (SNP) | VAF 171/528 reads (32%) | called by muse, mutect2, varscan2
- ATP6V0E1 | chr5:173020877 del GT | 3'Flank (DEL) | VAF 93/384 reads (24%) | called by pindel, varscan2
- ATP8B1 | c.699-15del | Intron (DEL) | VAF 28/101 reads (28%) | catalogued as rs35393039; called by mutect2, pindel, varscan2
- C1QTNF6 | c.289+853G>A | Intron (SNP) | VAF 16/267 reads (6%) | catalogued as rs1463725453; called by muse, mutect2
- C5orf38 | c.*19C>T | 3'UTR (SNP) | VAF 18/242 reads (7%) | catalogued as rs772152912, COSV100121710; called by muse, mutect2
- CAPS2 | c.*35del | 3'UTR (DEL) | VAF 18/48 reads (38%) | catalogued as rs754599424; called by mutect2, varscan2
- CLU | c.-29-1029del | Intron (DEL) | VAF 128/430 reads (30%) | called by mutect2, pindel, varscan2
- CNOT10 | c.-32C>T | 5'UTR (SNP) | VAF 19/266 reads (7%) | called by muse, mutect2
- DCBLD2 | c.571+70del | Intron (DEL) | VAF 20/49 reads (41%) | catalogued as rs780707032; called by mutect2, pindel, varscan2
- DCTN1 | c.3029+32C>A | Intron (SNP) | VAF 14/340 reads (4%) | called by muse, mutect2
- DNM1P46 | n.922C>T | RNA (SNP) | VAF 37/532 reads (7%) | catalogued as rs749687390; called by muse, mutect2
- FABP5P3 | chr7:152445798 G>A | 3'Flank (SNP) | VAF 137/442 reads (31%) | catalogued as rs145147830; called by muse, mutect2, varscan2
- GOLGA8N | c.348+24G>A | Intron (SNP) | VAF 28/220 reads (13%) | catalogued as rs544425963; called by mutect2, varscan2
- GPATCH2L | c.-11+809dup | Intron (INS) | VAF 44/127 reads (35%) | called by mutect2, pindel, varscan2
- KIF26B | c.999+3215G>A | Intron (SNP) | VAF 80/216 reads (37%) | catalogued as rs759296619, COSV68572750; called by muse, mutect2, varscan2
- LHX1 | c.675+63C>T | Intron (SNP) | VAF 28/356 reads (8%) | catalogued as rs1256971787; called by muse, mutect2
- MBTPS2 | c.-3G>A | 5'UTR (SNP) | VAF 201/605 reads (33%) | called by muse, mutect2, varscan2
- MIA2 | c.64-28del | Intron (DEL) | VAF 13/75 reads (17%) | called by mutect2, pindel, varscan2
- MMP19 | c.895+15dup | Intron (INS) | VAF 54/254 reads (21%) | called by mutect2, pindel, varscan2
- MUC20 | c.-1G>A | 5'UTR (SNP) | VAF 89/616 reads (14%) | catalogued as rs1450995354; called by muse, mutect2, varscan2
- MYB | c.1203+1204del | Intron (DEL) | VAF 79/302 reads (26%) | called by mutect2, pindel, varscan2
- MYH3 | c.349-26G>A | Intron (SNP) | VAF 80/337 reads (24%) | catalogued as rs781222080; called by muse, mutect2, varscan2
- NANOS3 | c.126+26C>T | Intron (SNP) | VAF 175/436 reads (40%) | catalogued as rs961040018; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2483G>A | Intron (SNP) | VAF 225/684 reads (33%) | called by muse, mutect2, varscan2
- NLRP12 | c.2244-162C>T | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as rs1427777239; called by muse, mutect2
- NUDT7 | c.190-338T>G | Intron (SNP) | VAF 14/74 reads (19%) | catalogued as rs191498435; called by muse, mutect2, varscan2
- NUP58 | c.107+1091T>G | Intron (SNP) | VAF 34/108 reads (31%) | called by muse, mutect2, varscan2
- OPA1 | c.1478-4del | Intron (DEL) | VAF 36/164 reads (22%) | called by mutect2, pindel, varscan2
- P4HTM | c.1074-11del | Intron (DEL) | VAF 17/52 reads (33%) | catalogued as rs760453324, COSV59086098; called by mutect2, pindel, varscan2
- PCDHGA3 | c.2425-66763C>T | Intron (SNP) | VAF 15/399 reads (4%) | called by muse, mutect2
- PDPN | c.67+28C>T | Intron (SNP) | VAF 56/202 reads (28%) | catalogued as rs750365640; called by muse, mutect2, varscan2
- PLPPR2 | c.*261C>A | 3'UTR (SNP) | VAF 54/244 reads (22%) | catalogued as COSV52261616; called by muse, mutect2, varscan2
- RAD51C | c.-12G>T | 5'UTR (SNP) | VAF 19/526 reads (4%) | called by muse, mutect2
- SH3GL3 | c.45+43255A>G | Intron (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- SHANK1 | c.1965-82C>T | Intron (SNP) | VAF 38/101 reads (38%) | catalogued as rs546911564, COSV99521169; called by muse, mutect2, varscan2
- SLTM | c.1108+68G>A | Intron (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2
- SSUH2 | n.486del | RNA (DEL) | VAF 12/41 reads (29%) | catalogued as rs1311798023; called by mutect2, pindel, varscan2
- UROD | c.943-19T>C | Intron (SNP) | VAF 98/344 reads (28%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439114 C>T | 5'Flank (SNP) | VAF 44/122 reads (36%) | called by muse, mutect2
- ZNF107 | c.-28del | 5'UTR (DEL) | VAF 12/81 reads (15%) | catalogued as rs752827791; called by mutect2, varscan2
